Gene-level copy-number profile of tumor specimen TCGA-RC-A6M5-01A from TCGA case TCGA-RC-A6M5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, fibrolamellar; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 20.9 years (7,634 days).
Specimen TCGA-RC-A6M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.29919962-5ed0-4289-8976-4fa1885449ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RC-A6M5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a0484e9-8222-49ed-b896-9bdeb3588f84

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,783; copy number 2: 54,318; copy number 3: 3,716.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RC-A6M5-01A-11D-A32F-01): tumor purity 0.25, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
